Gene-level copy-number profile of tumor specimen TCGA-EE-A3JB-06A from TCGA case TCGA-EE-A3JB, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 77.4 years (28,259 days).
Specimen TCGA-EE-A3JB-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.9dd70e84-d8d4-431e-8037-6a0d85c008b2.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EE-A3JB-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/122092e3-e71a-4f6f-b216-4a56f163852f

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,145; copy number 2: 18,179; copy number 3: 25,633; copy number 4: 11,371; copy number 5: 2,386; copy number 6: 207; copy number 7: 669; copy number 9: 63; copy number 10: 55; copy number 11: 10; copy number 31: 99.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-EE-A3JB-06A-11D-A219-01): tumor purity 0.52, ploidy 2.91, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 896 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:148,791,102–152,841,439, 99 genes, copy number 31 (broad region; genes not listed).
- chr4:49,588,772–55,219,973, 63 genes, copy number 9 (broad region; genes not listed).
- chr4:56,760,919–60,038,586, 40 genes, copy number 10: AC022483.1, RN7SL492P, RN7SL357P, SPINK2, Metazoa_SRP, Y_RNA, REST, AC069307.1, NOA1, POLR2B, RNU6-998P, IGFBP7, UBE2CP3, IGFBP7-AS1, AC111197.1, AC105390.1, RPS26P24, LINC02380, AC013724.1, AC107396.1, AC093725.2, AC093725.1, AC104790.1, SRIP1, AC096725.1, LINC02494, AC019133.1, AC017091.1, LINC02619, LINC02429, AC097501.1, AC108517.2, AC108517.1, Y_RNA, AC096588.1, AC093857.1, Y_RNA, RNU6-1325P, AC092596.1, AC097655.1.
- chr4:60,922,619–62,510,771, 15 genes, copy number 10: MIR548AG1, LINC02271, ADGRL3, RPL17P19, AC020741.1, AC108161.1, Y_RNA, ADGRL3-AS1, RPS15AP17, AC007511.1, RPL21P47, AC105313.1, AC074087.2, AC074087.1, HMGN1P11.
- chr4:64,606,418–70,607,288, 132 genes, copy number 7–11 (broad region; genes not listed).
- chr6:6,534,697–6,995,727, 12 genes, copy number 7: CNN3P1, LY86, AL031123.2, AL031123.3, AL031123.1, AL031123.4, AL031123.5, AL136361.1, BTF3P7, AL158817.1, RN7SL554P, AL139390.1.
- chr6:7,881,522–13,328,583, 80 genes, copy number 7 (within-gene range 3–7) (broad region; genes not listed).
- chr6:17,530,899–26,017,787, 133 genes, copy number 7 (broad region; genes not listed).
- chr6:34,189,780–40,715,363, 154 genes, copy number 7 (broad region; genes not listed).
- chr6:41,546,426–46,761,158, 149 genes, copy number 7 (broad region; genes not listed).
- chr6:57,314,805–60,723,898, 19 genes, copy number 7: PRIM2, MIR548U, FO680682.1, AL021368.3, AL021368.5, AL021368.1, AL021368.2, GUSBP4, AL021368.4, POM121L14P, LINC00680, AL445250.1, GAPDHP15, AL390237.1, RBBP4P4, AL603755.1, AC244258.1, GAPDHP41, AL590227.1.

Autosomal genes at a single copy (total copy number 1): 1,145. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
